Somatic mutation profile of tumor specimen TCGA-T3-A92M-01A (aliquot TCGA-T3-A92M-01A-31D-A391-08) from TCGA case TCGA-T3-A92M, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.7 years (19,247 days).
Specimen TCGA-T3-A92M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c965903-51c7-46a8-90f3-72d4da344486.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T3-A92M-10A (Blood Derived Normal), aliquot TCGA-T3-A92M-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58d04125-cf77-462b-9628-4242824b799f

The open-access MAF lists 357 somatic variants for this specimen: 277 protein-altering or splice-affecting, 76 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 76, Nonsense Mutation 31, Splice Site 4, Frame Shift Ins 4, Intron 3, Splice Region 2, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 39/90 reads (43%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- ACADVL | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50038465; called by muse, mutect2, varscan2
- ACADVL | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as rs965557488, COSV99138490; called by muse, mutect2, varscan2
- ACAN | c.4693G>A p.D1565N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100717968; called by muse, mutect2, varscan2
- ACSBG2 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.026); catalogued as COSV99397392; called by muse, mutect2, varscan2
- ACTR1B | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1235768582, COSV100008087; called by muse, mutect2, varscan2
- ADAMTS15 | c.1467T>A p.D489E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100143345; called by muse, mutect2
- ADCY7 | c.1691C>A p.S564Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV99575967; called by muse, varscan2
- ADCY9 | c.2094G>C p.E698D | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.581); catalogued as COSV53581879, COSV99569922; called by muse, mutect2, varscan2
- AGBL2 | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV100101644; called by muse, mutect2, varscan2
- AGO3 | c.1685C>G p.S562* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99868488; called by muse, mutect2, varscan2
- AGTPBP1 | c.2638G>A p.E880K (on ENST00000357081 / NM_001330701.2; = p.E840K on NM_015239.2) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV100429692; called by muse, mutect2, varscan2
- AHNAK | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.356); catalogued as COSV99947218, COSV99948500; called by muse, mutect2, varscan2
- ANGPTL1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as rs1328298793, COSV99328146; called by muse, mutect2, varscan2
- ANXA13 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV99146104; called by muse, mutect2
- AOX1 | c.2878G>C p.D960H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV101021927; called by muse, mutect2, varscan2
- AP5B1 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376002; called by muse, mutect2, varscan2
- APBA3 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV100349658; called by muse, mutect2, varscan2
- ARNT2 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1391966698, COSV100308957; called by muse, mutect2, varscan2
- ASAP2 | c.1712A>G p.D571G | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1009077989, COSV99856143; called by muse, mutect2, varscan2
- ASB4 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1311851949, COSV100367165; called by muse, mutect2, varscan2
- ATAD5 | c.5500G>C p.E1834Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV100035108; called by muse, mutect2, varscan2
- ATP13A3 | c.2626T>C p.Y876H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV99756940; called by muse, mutect2, varscan2
- ATP13A3 | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as rs1298526392, COSV99756944; called by muse, mutect2
- ATP13A4 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV99794456; called by muse, mutect2, varscan2
- ATP6V1B2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV52354942, COSV99369405; called by muse, mutect2
- B2M | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV62564013; called by muse, mutect2, varscan2
- BOLA1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs371656521; called by muse, mutect2, varscan2
- BRIP1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as rs762701532, COSV99370012; called by muse, mutect2, varscan2
- C17orf80 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs377002043, COSV52145830; called by muse, mutect2
- C1orf127 | c.1937C>G p.S646* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100983375, COSV100983475; called by muse, mutect2, varscan2
- C20orf27 | c.272A>G p.K91R (on ENST00000379772 / NM_001258429.2; = p.K116R on NM_001039140.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99422189; called by muse, mutect2, varscan2
- C21orf91 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1295038729, COSV99516024; called by muse, mutect2, varscan2
- CACNA1C | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as rs762756712, COSV59753249; called by muse, mutect2, varscan2
- CACNG7 | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 58/215 reads (27%) | catalogued as COSV55817948; called by muse, mutect2, varscan2
- CADM4 | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as COSV55929754, COSV99731508; called by muse, mutect2, varscan2
- CAMKMT | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV101034671; called by muse, mutect2, varscan2
- CAP2 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.464); catalogued as rs768638271, COSV100012413, COSV57735315; called by muse, mutect2, varscan2
- CARNS1 | c.1550C>A p.P517Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as COSV100321949; called by muse, mutect2
- CASKIN2 | c.2960C>G p.S987* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100050392; called by muse, mutect2, varscan2
- CASP8AP2 | c.1321A>G p.R441G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99387019; called by muse, mutect2, varscan2
- CASP8AP2 | c.1450A>T p.R484W | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99387021; called by muse, mutect2
- CATSPERD | c.1623C>A p.F541L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100486776; called by muse, mutect2, varscan2
- CD68 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV99548918; called by muse, mutect2, varscan2
- CDCA7L | c.52A>C p.N18H | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV100651066; called by muse, mutect2, varscan2
- CDH6 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV54068148; called by muse, mutect2, varscan2
- CDH8 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1280595648, COSV100181273; called by muse, mutect2, varscan2
- CFAP45 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776738795, COSV63648389; called by muse, mutect2, varscan2
- CFAP46 | c.8147G>C p.*2716Sext*4 | Nonstop Mutation (SNP) | VAF 36/214 reads (17%) | catalogued as rs542624364, COSV99584625; called by muse, mutect2, varscan2
- CHCHD1 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV100863390; called by muse, mutect2, varscan2
- CHRNA9 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs370590960; called by muse, mutect2, varscan2
- CLBA1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as COSV101121025; called by muse, mutect2, varscan2
- CLCA1 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV52325143, COSV52328036, COSV99322309; called by muse, mutect2, varscan2
- CNKSR1 | c.1387G>A p.D463N (on ENST00000374253 / NM_001297647.2; = p.D456N on NM_006314.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV100128361; called by muse, mutect2, varscan2
- CNKSR1 | c.1543G>A p.E515K (on ENST00000374253 / NM_001297647.2; = p.E508K on NM_006314.3) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100128362; called by muse, mutect2, varscan2
- CNTNAP4 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1180767691, COSV100271146; called by muse, mutect2, varscan2
- COL9A1 | c.1903T>A p.S635T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as COSV100294703; called by muse, varscan2
- CPEB3 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745558291, COSV99799342; called by muse, mutect2, varscan2
- CPQ | c.1071C>A p.Y357* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99611876; called by muse, mutect2, varscan2
- CPS1 | c.4132G>T p.A1378S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as CM063931, COSV99242881; called by muse, mutect2, varscan2
- CRX | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99704461; called by muse, mutect2
- CTNNAL1 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100336504; called by muse, mutect2, varscan2
- CTSV | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV99414372; called by muse, mutect2
- CYP4F12 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100215813; called by muse, mutect2, varscan2
- D2HGDH | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs927869057, COSV100344381, COSV100344715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAB1 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100139977; called by muse, mutect2, varscan2
- DEFB118 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as COSV99489182; called by muse, mutect2, varscan2
- DENND2A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99326069; called by muse, mutect2, varscan2
- DENND2D | c.1320G>C p.K440N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100718627; called by muse, mutect2, varscan2
- DGKI | c.2470C>T p.L824F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99934092; called by muse, mutect2, varscan2
- DGKK | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101052981; called by muse, mutect2, varscan2
- DHX36 | c.2924G>A p.R975K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100273564; called by muse, mutect2
- DIDO1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99825730; called by muse, mutect2, varscan2
- DIP2B | c.2671G>C p.V891L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV99998431; called by muse, mutect2, varscan2
- DNAJC2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99971238; called by muse, mutect2, varscan2
- DNAJC8 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as COSV99746235; called by muse, mutect2
- DPP10 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.412); catalogued as COSV100064257; called by muse, mutect2, varscan2
- DPPA4 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV100169409; called by muse, mutect2, varscan2
- DSCAML1 | c.1237G>T p.E413* (on ENST00000321322; = p.E353* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100355821, COSV58398914; called by muse, mutect2, varscan2
- DUOXA1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99973156; called by muse, mutect2, varscan2
- EIF2B4 | c.1270G>T p.A424S (on ENST00000347454 / NM_001034116.2; = p.A423S on NM_015636.3) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV100730635; called by muse, mutect2, varscan2
- EIF2B5 | c.1991A>C p.H664P (on ENST00000647909; = p.H656P on NM_003907.3) | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV99889223; called by muse, mutect2, varscan2
- ENOPH1 | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99908651; called by muse, mutect2, varscan2
- EPB41L4A | c.1975C>G p.Q659E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs1445079987, COSV99813289; called by muse, mutect2, varscan2
- EPN1 | c.543C>G p.S181R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99321855; called by muse, mutect2, varscan2
- EPS8L1 | c.1411G>C p.E471Q (on ENST00000201647 / NM_133180.3; = p.E344Q on NM_017729.3) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV99136100; called by muse, mutect2, varscan2
- EYS | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.023); catalogued as COSV100676375; called by muse, mutect2, varscan2
- FABP9 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.155); catalogued as COSV100986936; called by muse, mutect2
- FAM83H | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs372023850; called by muse, mutect2, varscan2
- FGA | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.188); catalogued as COSV100120361; called by muse, mutect2, varscan2
- FGD6 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100676549, COSV59694477; called by muse, mutect2
- FLG | c.7126G>A p.E2376K | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.224); catalogued as rs370103341; called by muse, mutect2, varscan2
- FLG | c.2954C>G p.P985R | Missense Mutation (SNP) | VAF 61/476 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100911529; called by muse, varscan2
- FOXP2 | c.1295C>G p.S432W | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100646263, COSV100646655; called by muse, mutect2, varscan2
- FSD2 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100575125; called by muse, mutect2
- FYCO1 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99945601; called by muse, mutect2, varscan2
- GART | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100738174, COSV63114766; called by muse, mutect2, varscan2
- GLIPR1L2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100157670; called by muse, mutect2
- GPAM | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100788196; called by muse, mutect2, varscan2
- GPR158 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as COSV100893447; called by muse, mutect2, varscan2
- GREB1 | c.4192C>A p.P1398T | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV99302852; called by muse, mutect2, varscan2
- H2BC8 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.32); catalogued as rs1448644205, COSV99773215; called by muse, mutect2, varscan2
- HDAC10 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs772325030, COSV99299323, COSV99299689; called by muse, mutect2
- HLA-A | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs41559912, CD098985, CM1412090, COSV65138924, COSV65139489; called by muse, mutect2, varscan2
- HLTF | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100026834; called by muse, mutect2, varscan2
- HMG20B | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs910167171, COSV53572237; called by muse, mutect2, varscan2
- HMMR | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100700993; called by muse, mutect2, varscan2
- HNRNPU | c.1036G>C p.D346H (on ENST00000283179; = p.D408H on NM_004501.3) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.875); catalogued as COSV99310248; called by muse, mutect2, varscan2
- HNRNPU | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99310249; called by muse, mutect2
- HTR7 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | catalogued as COSV53292144, COSV99518591; called by muse, mutect2, varscan2
- IFT172 | c.3893G>T p.C1298F | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as COSV99562434; called by muse, mutect2, varscan2
- IQGAP2 | c.2048G>C p.R683T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99167163; called by muse, mutect2, varscan2
- IREB2 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51921030, COSV99359355; called by muse, mutect2, varscan2
- KDM1A | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV100752567; called by muse, mutect2
- KIAA0232 | c.2731T>G p.Y911D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751616689, COSV100300673; called by muse, mutect2, varscan2
- KIF1B | c.4642C>G p.Q1548E (on ENST00000377086 / NM_001365952.1; = p.Q1502E on NM_015074.3) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.078); catalogued as rs1331941619, COSV99823180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFAP3 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs767240405, COSV100846913; called by muse, mutect2, varscan2
- KLKB1 | c.1572C>A p.F524L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV99249903; called by muse, mutect2, varscan2
- KMT2D | c.3398C>G p.S1133* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99981165; called by muse, mutect2, varscan2
- KRT74 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs964425929, COSV99977501; called by muse, mutect2, varscan2
- KSR2 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as rs776731615, CM1311361, COSV100194055, COSV56672951; called by muse, mutect2, varscan2
- LIPI | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as rs777439279, COSV100753667; called by muse, mutect2
- LMNB1 | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs762308044, COSV99745857, COSV99745897; called by muse, mutect2, varscan2
- LRIG2 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100743316; called by muse, mutect2, varscan2
- LRRC4C | c.707C>G p.P236R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV99538088; called by muse, varscan2
- LRRC4C | c.597G>C p.L199F | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53434326, COSV99538091; called by muse, varscan2
- LRRC73 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs977490987, COSV99446648; called by muse, mutect2
- MACF1 | c.6278G>A p.R2093K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99243987, COSV99245588; called by muse, mutect2, varscan2
- MACF1 | c.6454G>A p.D2152N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs1245358186, COSV99243992; called by muse, mutect2, varscan2
- MAN2A1 | c.2207A>G p.Y736C | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99810983; called by muse, mutect2, varscan2
- MAP1A | c.5762G>A p.R1921K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV100288605; called by muse, mutect2, varscan2
- MAP4K1 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV101204219; called by muse, mutect2, varscan2
- MAP9 | c.1259G>C p.R420T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV100250886; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.623); catalogued as rs765225360, COSV99167935; called by muse, mutect2, varscan2
- MAS1L | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.782); catalogued as COSV101009680; called by muse, mutect2, varscan2
- MDM2 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254521; called by muse, mutect2, varscan2
- MED16 | c.1356G>A p.L452= | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as rs755810516, COSV99515578; called by muse, mutect2
- MEI1 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100299911, COSV100300038; called by muse, mutect2, varscan2
- MGA | c.8105C>T p.S2702F (on ENST00000219905 / NM_001164273.1; = p.S2493F on NM_001080541.2) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99579799; called by muse, mutect2, varscan2
- MICAL3 | c.3646C>G p.L1216V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV101490858, COSV71588058; called by muse, mutect2, varscan2
- MLH3 | c.1501T>C p.C501R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.168); catalogued as COSV99470168; called by muse, mutect2
- MLLT10 | c.1946C>T p.S649L (on ENST00000307729 / NM_001195626.3; = p.S665L on NM_004641.3) | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs202106072; called by muse, mutect2
- MOB1A | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101247261; called by muse, mutect2, varscan2
- MORF4L1 | c.508C>T p.Q170* (on ENST00000331268 / NM_206839.2; = p.Q131* on NM_006791.4) | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100489108; called by muse, mutect2, varscan2
- MPRIP | c.2367G>C p.K789N | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100505646; called by muse, mutect2, varscan2
- MSC | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.067); catalogued as COSV100335670; called by muse, mutect2, varscan2
- MUC4 | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.044); catalogued as COSV100640441; called by muse, mutect2, varscan2
- MUC5B | c.11732G>A p.G3911E | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1402083904, COSV71594626; called by muse, mutect2
- MYO18B | c.3329C>G p.S1110W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100123513, COSV59132236; called by muse, mutect2, varscan2
- MYO1H | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183467; called by muse, mutect2, varscan2
- MYO5C | c.5045G>C p.R1682T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs760251847, COSV99953313; called by muse, mutect2, varscan2
- NEXMIF | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.241); catalogued as COSV50024533, COSV50087046, COSV99280656; called by muse, mutect2, varscan2
- NME8 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.585); catalogued as COSV99553226; called by muse, mutect2, varscan2
- NOS2 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs200750597, COSV58222527, COSV58223998; called by muse, mutect2, varscan2
- NPFFR2 | c.1471C>A p.H491N | Missense Mutation (SNP) | VAF 106/177 reads (60%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.057); catalogued as COSV100440652, COSV58150250; called by muse, mutect2, varscan2
- NR2C2AP | c.116G>A p.W39* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100284516; called by muse, mutect2, varscan2
- NRIP1 | c.3299C>G p.S1100* | Nonsense Mutation (SNP) | VAF 31/176 reads (18%) | catalogued as COSV100012649; called by muse, mutect2, varscan2
- NRROS | c.1612C>G p.L538V | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100145479; called by muse, mutect2, varscan2
- OBSL1 | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV54703033; called by muse, mutect2
- OR2T6 | c.870C>A p.Y290* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as COSV63216827; called by muse, mutect2, varscan2
- OR4F15 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.192); catalogued as rs766043618, COSV59969453; called by muse, mutect2, varscan2
- OR52N5 | c.652T>A p.F218I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV100399682; called by muse, mutect2, varscan2
- OR8J3 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs752420157, COSV100040798; called by muse, mutect2, varscan2
- OXTR | c.984C>G p.I328M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1158630940, COSV100373162, COSV100373388; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as COSV101250386; called by muse, mutect2, varscan2
- PBRM1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV56260728, COSV99968583; called by muse, mutect2, varscan2
- PCDHA12 | c.1115T>G p.I372S | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100250191; called by muse, mutect2, varscan2
- PCDHA9 | c.1610C>A p.A537E | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65324037, COSV65331516; called by muse, mutect2, varscan2
- PCDHAC2 | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782200456, COSV99146743; called by muse, mutect2, varscan2
- PCDHB1 | c.1388A>C p.E463A | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100128154; called by muse, mutect2, varscan2
- PCDHB5 | c.1706C>A p.A569E | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV99167589, COSV99167876; called by muse, mutect2, varscan2
- PCDHGB2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs753994650, COSV99537365; called by muse, mutect2, varscan2
- PGAP1 | c.2338-1G>A p.X780_splice | Splice Site (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100697969, COSV100698174; called by muse, mutect2, varscan2
- PHKB | c.2303G>A p.R768K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.173); catalogued as COSV100066886, COSV100068717; called by muse, mutect2
- PI16 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV101028680; called by muse, mutect2, varscan2
- PLAU | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101032330; called by muse, mutect2, varscan2
- PLCD1 | c.993-2A>C p.X331_splice | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99378766; called by muse, mutect2, varscan2
- PLD5 | c.1481G>A p.W494* (on ENST00000442594; = p.W432* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/246 reads (12%) | catalogued as COSV100140195; called by muse, mutect2, varscan2
- PLEKHA7 | c.1816G>C p.D606H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100850249; called by muse, mutect2
- PMEL | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100093028; called by muse, mutect2
- PNPLA1 | c.737G>A p.R246Q (on ENST00000394571 / NM_001374623.1; = p.R151Q on NM_173676.2) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.153); catalogued as rs746575171, COSV100463037; called by muse, mutect2
- POLQ | c.2729C>T p.S910L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1463427483, COSV99952167; called by muse, mutect2, varscan2
- POM121L12 | c.834C>A p.C278* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as rs1254653424, COSV101374913, COSV68693002; called by muse, mutect2, varscan2
- PREX2 | c.4465T>C p.F1489L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV99906958; called by muse, mutect2, varscan2
- PRMT8 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99713366; called by muse, mutect2, varscan2
- PROS1 | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs778685576, CM961195, CM992962, COSV101260447, COSV99059804; called by muse, mutect2, varscan2
- PRRC2A | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100784517, COSV100784573; called by muse, mutect2, varscan2
- PTPRS | c.677A>T p.Y226F | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV53608768, COSV99510384; called by muse, mutect2, varscan2
- QDPR | c.280A>C p.N94H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99845805; called by muse, mutect2, varscan2
- RAC2 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.942); catalogued as COSV50775842; called by muse, mutect2, varscan2
- RANBP2 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.834); catalogued as COSV51695847, COSV99312021; called by muse, mutect2, varscan2
- RBPJL | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs369083610; called by muse, mutect2, varscan2
- RBSN | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs769332888, COSV53791944; called by muse, mutect2, varscan2
- RIMBP2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55471098; called by muse, mutect2, varscan2
- RNF103 | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99410134; called by muse, mutect2
- RNF168 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100534949, COSV58838058; called by muse, mutect2
- RNF168 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV58836764; called by muse, mutect2, varscan2
- RNF19B | c.1797C>A p.H599Q | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV99331425; called by muse, mutect2, varscan2
- RPLP0 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99935363; called by muse, mutect2, varscan2
- RTN4 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100463109; called by muse, mutect2, varscan2
- RUBCN | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99583923; called by muse, mutect2
- RUNX1 | c.703C>G p.Q235E (on ENST00000344691 / NM_001001890.3; = p.Q262E on NM_001754.5) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as CM1210373, COSV100277318, COSV55866493; called by muse, mutect2, varscan2
- RXFP1 | c.1522T>A p.L508M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100313740; called by muse, mutect2, varscan2
- SAFB | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.079); catalogued as rs200348280, COSV52652715; called by muse, mutect2, varscan2
- SCP2 | c.1338G>A p.E446= | Splice Region (SNP) | VAF 3/23 reads (13%) | catalogued as rs1306257154, COSV101027029; called by muse, mutect2
- SEC16B | c.1815G>C p.Q605H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100381538; called by muse, mutect2, varscan2
- SF3B1 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV100134616, COSV59225618; called by muse, mutect2, varscan2
- SIX4 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV99382234; called by muse, mutect2, varscan2
- SLAMF6 | c.902G>C p.R301T (on ENST00000368057 / NM_001184714.2; = p.R300T on NM_052931.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100924880; called by muse, mutect2
- SLAMF9 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100928132; called by muse, mutect2, varscan2
- SLC12A7 | c.2379G>C p.M793I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV99369802; called by muse, mutect2
- SLC12A8 | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.689); catalogued as rs965635380, COSV100102299; called by muse, mutect2, varscan2
- SLC17A7 | c.1530C>G p.F510L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV55548826; called by muse, mutect2, varscan2
- SLC26A3 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.144); catalogued as COSV100385020; called by muse, mutect2
- SLC5A2 | c.1386C>A p.Y462* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100393168; called by muse, mutect2, varscan2
- SLC9A9 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs775249012, COSV57216495; called by muse, mutect2
- SMG6 | c.1948C>G p.Q650E | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99558141; called by muse, mutect2, varscan2
- SOS2 | c.2830G>C p.D944H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99366006; called by muse, mutect2
- SPI1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99908876; called by mutect2, varscan2
- STK19 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.19); catalogued as COSV100514643; called by muse, mutect2, varscan2
- SUCLA2 | c.1303G>A p.D435N (on ENST00000643023; = p.D414N on NM_003850.3) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.362); catalogued as rs760414248, COSV66222024; called by muse, mutect2, varscan2
- SUPT6H | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); catalogued as COSV100112370; called by muse, mutect2, varscan2
- SYNE1 | c.17930C>T p.T5977M (on ENST00000367255 / NM_182961.4; = p.T5906M on NM_033071.3) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs767144952, COSV99562670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT10 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs866874853, COSV104391111, COSV57337722; called by muse, mutect2, varscan2
- TAF1A | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | catalogued as COSV100600972; called by muse, mutect2, varscan2
- TENM2 | c.5200G>C p.D1734H (on ENST00000518659 / NM_001122679.2; = p.D1495H on NM_001080428.3) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV101318608; called by muse, mutect2
- TET1 | c.2702C>T p.S901L | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65382384, COSV65383077; called by muse, mutect2, varscan2
- TFRC | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV100786452, COSV64056979; called by muse, mutect2, varscan2
- TJP1 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62040220; called by muse, mutect2, varscan2
- TM9SF3 | c.1571C>G p.S524* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100951846; called by muse, mutect2, varscan2
- TMC4 | c.1057C>G p.L353V (on ENST00000617472 / NM_001145303.3; = p.L347V on NM_144686.4) | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as COSV99713840; called by muse, mutect2, varscan2
- TMEM266 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423749413, COSV101189615, COSV66380811; called by muse, mutect2, varscan2
- TNIP3 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV99284454; called by muse, mutect2, varscan2
- TNR | c.35A>C p.N12T | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.079); catalogued as COSV99689370; called by muse, mutect2, varscan2
- TONSL | c.3523C>G p.L1175V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV101340233; called by muse, mutect2, varscan2
- TPH1 | c.935A>T p.Y312F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.774); catalogued as COSV100000821; called by muse, mutect2, varscan2
- TRIM52 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100580762; called by mutect2, varscan2
- TSBP1 | c.667A>T p.K223* (on ENST00000617061; = p.K226* on NM_006781.5) | Nonsense Mutation (SNP) | VAF 23/139 reads (17%) | catalogued as COSV100898782; called by muse, mutect2, varscan2
- TSKS | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99883251; called by muse, mutect2, varscan2
- TTN | c.25030C>T p.H8344Y (on ENST00000591111; = p.H7417Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/114 reads (10%) | PolyPhen benign (0.244); catalogued as COSV60081997; called by muse, mutect2, varscan2
- TVP23B | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100314516; called by muse, mutect2
- UGGT1 | c.3251C>T p.S1084F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99390673; called by muse, mutect2, varscan2
- UHRF1 | c.515C>G p.S172C (on ENST00000612630 / NM_001290050.1; = p.S185C on NM_013282.4) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV53577211; called by muse, mutect2, varscan2
- UNC79 | c.1214A>G p.K405R (on ENST00000393151 / NM_001346218.2; = p.K228R on NM_020818.5) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV99827618; called by muse, mutect2, varscan2
- USP29 | c.659G>C p.R220T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54141399, COSV54146649; called by muse, mutect2, varscan2
- USP34 | c.3154C>G p.L1052V | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV101276979; called by muse, mutect2
- VPS26C | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs750534462, COSV99898448; called by muse, mutect2, varscan2
- VWA7 | c.2348C>A p.S783* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | catalogued as COSV100991823, COSV65172653; called by muse, mutect2
- WDR3 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV62523206; called by muse, mutect2, varscan2
- WNT16 | c.653C>A p.S218* (on ENST00000222462 / NM_057168.2; = p.S208* on NM_016087.2) | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99743106; called by muse, mutect2, varscan2
- YTHDC2 | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99363231; called by muse, mutect2, varscan2
- ZHX1 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as rs777615439, COSV99933647; called by muse, mutect2
- ZMYM3 | c.3956A>G p.Y1319C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077805; called by muse, mutect2, varscan2
- ZNF107 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV100788354; called by muse, mutect2, varscan2
- ZNF208 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101237012; called by muse, mutect2, varscan2
- ZNF211 | c.736C>T p.Q246* (on ENST00000347302 / NM_198855.4; = p.Q259* on NM_006385.5) | Nonsense Mutation (SNP) | VAF 20/127 reads (16%) | catalogued as COSV99560248; called by muse, mutect2, varscan2
- ZNF285 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100449980; called by muse, mutect2, varscan2
- ZNF404 | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100182525; called by muse, mutect2, varscan2
- ZNF420 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as COSV100421327; called by muse, mutect2, varscan2
- ZNF432 | c.1892G>C p.R631T | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs1413002245, COSV99659233; called by muse, mutect2, varscan2
- ZNF442 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV99664354; called by muse, mutect2, varscan2
- ZNF501 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); catalogued as COSV101247097; called by muse, mutect2, varscan2
- ZNF529 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.338); catalogued as COSV100485199, COSV61901265; called by muse, mutect2, varscan2
- ZNF585B | c.959A>T p.H320L | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100459420; called by muse, mutect2, varscan2
- ZNF8 | c.1277A>G p.E426G | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.34); catalogued as COSV99544285; called by muse, mutect2, varscan2
- ZNF85 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV100059737, COSV56021089; called by muse, mutect2, varscan2
- ZNHIT1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752727634, COSV59313511; called by muse, mutect2, varscan2
- ADIPOQ | c.581dup p.D195Gfs*28 | Frame Shift Ins (INS) | VAF 16/116 reads (14%) | called by mutect2, pindel, varscan2
- CFAP74 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM83C | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- IGHG3 | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MACF1 | c.13111_13112del p.X4371_splice (on ENST00000372915; = p.X2304_splice on NM_012090.5) | Splice Site (DEL) | VAF 7/65 reads (11%) | called by pindel, varscan2
- PKD1L2 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- SACM1L | c.1695dup p.I566Yfs*76 | Frame Shift Ins (INS) | VAF 24/122 reads (20%) | called by mutect2, pindel, varscan2
- SLC22A5 | c.1266dup p.D423Rfs*100 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- SRSF10 | c.223T>C p.W75R | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF750 | c.105_106dup p.E36Vfs*10 | Frame Shift Ins (INS) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- ABHD14B | c.624G>A p.G208= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100258996; called by muse, mutect2, varscan2
- ABRA | c.243G>A p.S81= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs766133371, COSV61732524; called by muse, mutect2, varscan2
- ACP2 | c.1179C>T p.F393= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1355805126, COSV99921627; called by muse, mutect2, varscan2
- ANAPC4 | c.1995C>G p.L665= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100193980; called by muse, mutect2, varscan2
- ARHGAP31 | c.3273G>A p.K1091= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as COSV99957049; called by muse, mutect2, varscan2
- C1orf56 | c.990C>T p.F330= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99764637; called by muse, mutect2, varscan2
- CDC42BPB | c.954G>A p.Q318= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs778365484, COSV100775417; called by muse, mutect2, varscan2
- CDCP2 | c.465C>T p.V155= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100313455; called by muse, mutect2, varscan2
- CEACAM20 | c.222C>T p.V74= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV100386869; called by muse, mutect2, varscan2
- CENPE | c.2664G>A p.E888= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99477807; called by muse, mutect2, varscan2
- CLIP3 | c.1242C>G p.A414= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV99431025; called by muse, mutect2, varscan2
- COL6A3 | c.7416G>A p.K2472= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99797989; called by muse, mutect2
- COL8A1 | c.1689C>A p.G563= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs923788839, COSV99657669; called by muse, mutect2, varscan2
- COQ6 | c.231G>A p.E77= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99473984; called by muse, mutect2
- CPNE8 | c.1185G>T p.G395= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV100504310; called by muse, mutect2, varscan2
- DHRS12 | c.711G>A p.V237= (on ENST00000444610 / NM_001377930.1; = p.V188= on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99523671, COSV99523818; called by muse, mutect2, varscan2
- DYNC1LI2 | c.396C>T p.L132= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs1461736318, COSV99263006; called by muse, mutect2, varscan2
- ECSIT | c.423C>T p.F141= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99369003; called by muse, mutect2, varscan2
- EIF2B4 | c.1464C>A p.V488= (on ENST00000347454 / NM_001034116.2; = p.V487= on NM_015636.3) | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100730633; called by muse, mutect2, varscan2
- ELAC2 | c.834C>G p.V278= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs138869157, COSV100568477; called by muse, mutect2, varscan2
- FANCC | c.1476C>G p.L492= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100002407; called by muse, mutect2, varscan2
- FAT4 | c.13002T>C p.T4334= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100628482; called by muse, mutect2, varscan2
- FBXL7 | c.1305C>G p.L435= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100309690; called by muse, mutect2
- FER1L6 | c.396C>T p.F132= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs769245915, COSV67550050; called by muse, mutect2, varscan2
- FERMT3 | c.204G>A p.Q68= | Silent (SNP) | VAF 45/214 reads (21%) | catalogued as COSV99656554; called by muse, mutect2, varscan2
- FUT8 | c.1014A>G p.P338= (on ENST00000360689 / NM_001371534.1; = p.P175= on NM_004480.4) | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100651351; called by muse, mutect2, varscan2
- GOLGA2 | c.789C>G p.V263= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV101425869; called by muse, mutect2, varscan2
- HOXB8 | c.570C>G p.V190= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs1292886577, COSV53311007, COSV99494047; called by muse, mutect2, varscan2
- HSPA2 | c.723G>T p.V241= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV99904915; called by muse, mutect2
- HUWE1 | c.12786G>C p.L4262= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1556910115, COSV99472057; called by muse, mutect2, varscan2
- IL5RA | c.513C>T p.L171= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV56521325, COSV99842956; called by muse, mutect2, varscan2
- ISL1 | c.660C>T p.L220= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100045358; called by muse, mutect2
- KIFAP3 | c.81C>G p.L27= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100846914; called by muse, mutect2, varscan2
- KPRP | c.1050C>T p.I350= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1557827993, COSV100908697, COSV64222956; called by muse, mutect2, varscan2
- LAD1 | c.687G>A p.K229= | Silent (SNP) | VAF 30/274 reads (11%) | catalogued as COSV100943840; called by muse, mutect2, varscan2
- LHFPL1 | c.285G>T p.L95= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100914454; called by muse, mutect2, varscan2
- LILRA2 | c.642G>A p.E214= | Silent (SNP) | VAF 12/263 reads (5%) | catalogued as COSV52197075; called by muse, mutect2
- LRCH4 | c.1794C>G p.L598= | Silent (SNP) | VAF 31/269 reads (12%) | catalogued as COSV99776210; called by muse, mutect2, varscan2
- LRP1 | c.1422G>A p.R474= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs138294603; called by muse, mutect2, varscan2
- LRP1B | c.5952T>C p.G1984= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV101256255; called by muse, mutect2, varscan2
- LTN1 | c.1338C>G p.L446= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV63733134; called by muse, mutect2, varscan2
- MEX3B | c.441C>G p.L147= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100314017; called by muse, mutect2, varscan2
- NCAPD2 | c.231C>G p.L77= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100217131; called by muse, mutect2, varscan2
- NMRK2 | c.531G>A p.E177= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV99396337; called by muse, mutect2, varscan2
- NR1H3 | c.1251G>C p.L417= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV100211407; called by muse, mutect2
- NSUN3 | c.396G>T p.G132= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100113246; called by muse, mutect2
- OLFML1 | c.42G>C p.L14= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100252594; called by muse, mutect2, varscan2
- OPCML | c.801G>A p.L267= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100100795; called by muse, mutect2, varscan2
- OR10G4 | c.714G>A p.Q238= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100304744, COSV100304816; called by muse, mutect2, varscan2
- PGBD4 | c.675G>A p.K225= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1260969943, COSV99854825; called by muse, mutect2, varscan2
- RAVER1 | c.115C>T p.L39= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99349021; called by muse, mutect2
- SAMD7 | c.471C>T p.L157= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as COSV100156898; called by muse, mutect2
- SAPCD1 | c.369G>A p.Q123= (on ENST00000425424; = p.Q153= on NM_001039651.1) | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100991822; called by muse, mutect2, varscan2
- SDK1 | c.6408G>C p.A2136= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV101268644, COSV101269344; called by muse, mutect2, varscan2
- SETDB2 | c.2010G>A p.R670= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100422565; called by muse, mutect2, varscan2
- SFTPB | c.561G>A p.A187= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs543913426, COSV60892598; called by muse, varscan2
- SLC3A2 | c.1356C>T p.L452= | Silent (SNP) | VAF 12/287 reads (4%) | catalogued as COSV100101355; called by muse, mutect2
- SLC6A3 | c.93C>G p.L31= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99548243; called by muse, mutect2, varscan2
- SMOX | c.1470C>T p.S490= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs757237978, COSV53869745; called by muse, mutect2, varscan2
- SSH1 | c.642C>T p.I214= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs753945153, COSV100425501; called by muse, mutect2, varscan2
- SUN1 | c.1596G>C p.V532= (on ENST00000405266 / NM_001367651.1; = p.V412= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 30/313 reads (10%) | catalogued as COSV101273036; called by muse, mutect2
- SYNE2 | c.162A>C p.I54= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100420178; called by muse, mutect2, varscan2
- SYPL1 | c.498G>A p.V166= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99163442; called by muse, mutect2, varscan2
- TAS2R4 | c.708C>T p.L236= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs1261337026, COSV99924660; called by muse, mutect2, varscan2
- TBXA2R | c.72G>A p.L24= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV64343293; called by muse, mutect2, varscan2
- TCAF1 | c.447C>T p.L149= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs371535446, COSV100584621; called by muse, mutect2, varscan2
- TG | c.4206G>A p.L1402= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV55084362, COSV99600625; called by muse, mutect2, varscan2
- TRAPPC4 | c.6G>T p.A2= | Silent (SNP) | VAF 42/177 reads (24%) | catalogued as COSV100548640, COSV57723252; called by muse, mutect2, varscan2
- TTN | c.97638C>T p.Y32546= (on ENST00000591111; = p.Y25122= on NM_003319.4) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs375625664; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- USP1 | c.1680T>A p.L560= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV99224252; called by muse, mutect2, varscan2
- VCAN | c.93G>A p.P31= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs771456960, COSV54105046; called by muse, mutect2, varscan2
- ZGLP1 | c.393G>A p.L131= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100593761; called by muse, mutect2, varscan2
- ZHX3 | c.699C>T p.I233= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV100475426, COSV58387934; called by muse, mutect2, varscan2
- ZNF212 | c.468G>A p.E156= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs762760713, COSV60025963; called by muse, mutect2, varscan2
- ZNF404 | c.804G>C p.V268= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100182454; called by muse, mutect2, varscan2
- ZNF99 | c.126C>T p.F42= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs1181125016, COSV101233818; called by muse, mutect2
- AOPEP | c.*5-1160C>A | Intron (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99949581; called by muse, mutect2, varscan2
- DENND10P1 | n.1248G>T | RNA (SNP) | VAF 7/15 reads (47%) | called by mutect2, varscan2
- KLHL7 | c.121-5867C>T | Intron (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100178036; called by muse, mutect2
- SDF4 | c.892-17G>A | Intron (SNP) | VAF 9/92 reads (10%) | catalogued as rs1233669242, COSV99767599; called by muse, mutect2, varscan2
